Somatic mutation profile of cancer-model specimen HCM-BROD-0421-C71-85A (Mixed Adherent Suspension, passage 12; aliquot HCM-BROD-0421-C71-85A-01D-A80U-36), derived from the primary tumor of HCMI case HCM-BROD-0421-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.7 years (18,165 days).
Specimen HCM-BROD-0421-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5456e352-fb25-4e9b-9d5e-f7b916475e9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0421-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0421-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d1564f1-eb93-4579-9f2a-58106c6edba5

The open-access MAF lists 85 somatic variants for this specimen: 57 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 27, Nonsense Mutation 4, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 92/146 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs1487171239, COSV57492723; called by muse, mutect2, varscan2
- C5 | c.270A>T p.K90N | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV56330938; called by muse, mutect2, varscan2
- CACNA1I | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 386/506 reads (76%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.5); catalogued as rs1278074840, COSV60802941; called by muse, mutect2, varscan2
- DGKD | c.1491C>A p.H497Q (on ENST00000264057 / NM_152879.3; = p.H453Q on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/260 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs201074042; called by muse, mutect2, varscan2
- HEG1 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 68/432 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs774887083; called by muse, mutect2, varscan2
- IGSF1 | c.3284C>T p.T1095I | Missense Mutation (SNP) | VAF 18/331 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as rs1224417790, COSV100811764; called by muse, mutect2
- ISL1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 12/236 reads (5%) | catalogued as COSV57936039; called by muse, mutect2
- KSR2 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 187/726 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs775572595, COSV60370056; called by muse, mutect2, varscan2
- NLRP4 | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 116/500 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs778909548, COSV100015860; called by muse, mutect2, varscan2
- OR4Q2 | c.103T>C p.Y35H | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1169457996; called by muse, mutect2, varscan2
- PDS5B | c.3851C>T p.P1284L | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as rs1308227017, COSV100220469, COSV59737349; called by muse, mutect2, varscan2
- PLA2G4F | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs769710297; called by mutect2, varscan2
- PLEKHN1 | c.1703G>A p.G568D (on ENST00000379409; = p.G516D on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 261/499 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV58021791; called by muse, mutect2, varscan2
- PLXND1 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 75/523 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.702); catalogued as rs1418833570; called by muse, mutect2, varscan2
- SPACA7 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 189/430 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs777305307; called by muse, mutect2, varscan2
- SSTR5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 286/604 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149886925; called by muse, mutect2, varscan2
- STAG1 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 47/299 reads (16%) | catalogued as COSV52605355; called by muse, mutect2, varscan2
- TTN | c.10131G>T p.W3377C (on ENST00000591111; = p.W3331C on NM_003319.4) | Missense Mutation (SNP) | VAF 77/115 reads (67%) | PolyPhen probably damaging (0.999); catalogued as COSV100616273; called by muse, mutect2, varscan2
- UBE2Q1 | c.704del p.K235Rfs*8 | Frame Shift Del (DEL) | VAF 79/388 reads (20%) | catalogued as COSV52724218; called by mutect2, pindel, varscan2
- ZER1 | c.2178dup p.M727Dfs*9 | Frame Shift Ins (INS) | VAF 73/591 reads (12%) | catalogued as rs1244464686; called by mutect2, pindel, varscan2
- ZNF469 | c.5779G>A p.A1927T (on ENST00000437464; = p.A1955T on NM_001367624.2) | Missense Mutation (SNP) | VAF 87/500 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.239); catalogued as rs772675428; called by muse, mutect2, varscan2
- ZNF598 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs761237206; called by muse, mutect2, varscan2
- ZSCAN5B | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 88/696 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs764485473, COSV61999615; called by muse, mutect2, varscan2
- ATP6V0D1 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 172/358 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C2CD3 | c.5924C>A p.S1975Y | Missense Mutation (SNP) | VAF 23/353 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.81); called by muse, mutect2
- CCR2 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2
- CDK8 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRTAC1 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 122/543 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTLA4 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DLL3 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 282/1071 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2
- EPHA8 | c.1115C>A p.A372E | Missense Mutation (SNP) | VAF 106/528 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRL4 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- IGLV3-10 | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IHH | c.709A>T p.S237C | Missense Mutation (SNP) | VAF 322/469 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- INPP5B | c.1073C>T p.S358F (on ENST00000373023; = p.S278F on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 146/304 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- JARID2 | c.958A>G p.T320A | Missense Mutation (SNP) | VAF 75/352 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM6A | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 18/549 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- KIAA1755 | c.122A>C p.Q41P | Missense Mutation (SNP) | VAF 81/884 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2
- ME2 | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MEP1A | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 64/504 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2
- MIA3 | c.1970G>T p.W657L | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ODF2 | c.209dup p.G71Wfs*37 (on ENST00000434106 / NM_153433.2; = p.G115Wfs*37 on NM_153432.1 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 99/604 reads (16%) | called by mutect2, pindel, varscan2
- OTOP2 | c.1355A>T p.D452V | Missense Mutation (SNP) | VAF 122/786 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PAEP | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- PCSK5 | c.1831A>T p.K611* | Nonsense Mutation (SNP) | VAF 69/487 reads (14%) | called by muse, mutect2, varscan2
- PDGFRA | c.925G>T p.V309F | Missense Mutation (SNP) | VAF 251/444 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PNPLA5 | c.221T>G p.M74R | Missense Mutation (SNP) | VAF 153/549 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- RBM42 | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 139/1160 reads (12%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- RTTN | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SPOCD1 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 48/343 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SUGP2 | c.329A>T p.D110V | Missense Mutation (SNP) | VAF 125/378 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- TEP1 | c.1363C>A p.Q455K | Missense Mutation (SNP) | VAF 83/447 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- TRPC7 | c.2419+1G>T p.X807_splice | Splice Site (SNP) | VAF 251/251 reads (100%) | called by muse, mutect2, varscan2
- TSLP | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- YIPF6 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF654 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 13/211 reads (6%) | called by muse, mutect2
- ZNF831 | c.3776A>G p.H1259R | Missense Mutation (SNP) | VAF 131/403 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ADGRE1 | c.1959C>T p.L653= | Silent (SNP) | VAF 128/410 reads (31%) | catalogued as rs1460101498, COSV99165741; called by muse, mutect2, varscan2
- ADRB2 | c.822G>A p.T274= | Silent (SNP) | VAF 385/385 reads (100%) | catalogued as rs780458948; called by muse, mutect2, varscan2
- ALDH8A1 | c.387G>A p.T129= | Silent (SNP) | VAF 196/480 reads (41%) | catalogued as rs77178086, COSV55640193; called by muse, mutect2, varscan2
- ATP5MD | c.120G>A p.L40= | Silent (SNP) | VAF 38/107 reads (36%) | called by muse, varscan2
- C4orf54 | c.2649C>T p.D883= | Silent (SNP) | VAF 115/439 reads (26%) | catalogued as rs1448271611; called by muse, mutect2, varscan2
- CRYBG2 | c.1698G>T p.V566= | Silent (SNP) | VAF 101/461 reads (22%) | called by muse, varscan2
- DOP1B | c.4461C>T p.Y1487= | Silent (SNP) | VAF 130/378 reads (34%) | catalogued as rs755240356; called by muse, mutect2, varscan2
- DSEL | c.3402G>C p.L1134= | Silent (SNP) | VAF 127/270 reads (47%) | catalogued as COSV100025185; called by muse, mutect2, varscan2
- FAM47A | c.1674G>A p.P558= | Silent (SNP) | VAF 243/353 reads (69%) | catalogued as rs372486528, COSV60493816, COSV60495716; called by muse, mutect2, varscan2
- FOXA3 | c.828C>T p.P276= | Silent (SNP) | VAF 124/919 reads (13%) | catalogued as rs772799849; called by muse, mutect2, varscan2
- FPR1 | c.378C>T p.C126= | Silent (SNP) | VAF 86/742 reads (12%) | catalogued as rs776424230, CM995226, COSV59053255; called by muse, varscan2
- GBP4 | c.795C>T p.D265= | Silent (SNP) | VAF 97/187 reads (52%) | catalogued as rs539360281; called by muse, mutect2, varscan2
- GRIN2C | c.1824G>A p.A608= | Silent (SNP) | VAF 40/724 reads (6%) | catalogued as rs200900188, COSV53110784; called by muse, mutect2
- GRK1 | c.1587C>T p.G529= | Silent (SNP) | VAF 101/461 reads (22%) | catalogued as rs553489781; called by muse, mutect2, varscan2
- LCORL | c.4179G>A p.S1393= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as rs370477364; called by muse, mutect2, varscan2
- LILRA1 | c.438C>G p.V146= | Silent (SNP) | VAF 139/922 reads (15%) | catalogued as rs1292548651, COSV99251865; called by muse, mutect2, varscan2
- MXRA5 | c.39G>T p.V13= | Silent (SNP) | VAF 71/511 reads (14%) | called by muse, mutect2, varscan2
- MYH11 | c.267C>T p.D89= | Silent (SNP) | VAF 144/541 reads (27%) | called by muse, mutect2, varscan2
- MYO18B | c.3441G>A p.E1147= | Silent (SNP) | VAF 81/808 reads (10%) | called by muse, mutect2, varscan2
- PAN3 | c.1476C>T p.N492= | Silent (SNP) | VAF 55/252 reads (22%) | called by muse, mutect2, varscan2
- RIPPLY1 | c.39T>C p.V13= | Silent (SNP) | VAF 156/467 reads (33%) | called by muse, mutect2, varscan2
- RYBP | c.495A>G p.E165= | Silent (SNP) | VAF 115/416 reads (28%) | called by muse, mutect2, varscan2
- SLC25A25 | c.549G>A p.T183= | Silent (SNP) | VAF 87/792 reads (11%) | catalogued as rs772842561; called by muse, mutect2, varscan2
- SPOCD1 | c.795G>A p.G265= | Silent (SNP) | VAF 47/341 reads (14%) | called by muse, mutect2, varscan2
- ST14 | c.642C>T p.C214= | Silent (SNP) | VAF 77/394 reads (20%) | called by muse, mutect2, varscan2
- TPSD1 | c.291G>T p.L97= | Silent (SNP) | VAF 315/734 reads (43%) | called by muse, mutect2, varscan2
- UMOD | c.498C>T p.D166= | Silent (SNP) | VAF 136/562 reads (24%) | catalogued as rs1404722955; called by muse, mutect2, varscan2
- SLC5A10 | c.983-43C>T | Intron (SNP) | VAF 141/349 reads (40%) | catalogued as COSV100525351; called by muse, mutect2, varscan2
